Surgical pathology report (de-identified scan), TCGA case TCGA-06-0216, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0216-01A (Primary Tumor).

PATH.NO:

TCGA-06-0216

PATHOLOGICAL DIAGNOSIS:

BRAIN, OCCIPITAL LOBE: GLIOBLASTOMA MULTIFORME, MIB-1: 50%.

Operation/Specimen: Occipital mass.

Clinical History and Pre-Op Dx: Crani for tumor.

GROSS PATHOLOGY:

A.
SPECIMEN: Small tissue fragment 0.2 cm.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma in #1,2.

B.
SPECIMEN: 2, right occipital mass.
FIXATIVE: None.
GENERAL: 4.0 x 2.5 x 1.3 cm. portion of partially fragmented, tan
maroon hemorrhagic soft tissue mass. Cut surface is
variegated, fleshy tan to chalky yellow-gray, serially
sectioned.
SECTIONS: 3-6 - all submitted.

MICROSCOPIC: Sections show a high grade glioma with hypercellularity -
nuclear hyperchromasia and pleomorphism, mitotic figures, vascular
hyperplasia and tumor necrosis. The MIB-1 labeling index is more than
50%.

Source: NCI Genomic Data Commons file cf7f9751-25bf-4c22-ade5-6a9b9de5501a (TCGA-06-0216.2E57F899-8D3F-4BE7-99BA-095F58B2E89C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).